Surgical pathology report (de-identified scan), TCGA case TCGA-SI-A71O, project TCGA-SARC (Sarcoma), tissue source site Washington University St. Louis, specimen TCGA-SI-A71O-01A (Primary Tumor).

[page 1 of 3]
Patient Name: [REDACTED]

DOB: [REDACTED]

Patient ID: [REDACTED]

Surgical Pathology Report

Final

EW-0-3
Tumor peripheral sheath
malignant 954513
Site Soft tissue @ hip C49.2
W8/9/13

SURGICAL PATHOLOGY REPORT FINAL WITH ADDENDUM

Patient Name: [REDACTED]

Address: [REDACTED]

Service: [REDACTED]

Accession: [REDACTED]

Taken: [REDACTED]

Gender: [REDACTED]

DOB: [REDACTED]

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type: [REDACTED]

Received: [REDACTED]

Accessioned: [REDACTED]

Reported: [REDACTED]

Physician(s): [REDACTED]

DIAGNOSIS:

SOFT TISSUE, RIGHT HIP, EXCISION - MALIGNANT PERIPHERAL NERVE SHEATH TUMOR

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

Report Electronically Reviewed and Signed On 07/09/13

Intraoperative Consultation:

FS: Right hip mass

- "Malignant spindle cell tumor," by

Microscopic Description and Comment:

Sections show a spindle cell sarcoma that varies from well formed spindle cells to areas with highly pleomorphic and anaplastic cells. Mitotic figures, many abnormal, are easily found. Osteoclasts-type giant cells are locally present, as are foci of osteoid produced by malignant stromal cells consistent with osteosarcoma. Immunostains show tumor cell reactivity for vimentin and CD57, with non-reactivity for smooth muscle actin, S100 protein, Melan-A, muscle specific actin, and h-Caldesmon. Based on the results, we believe that this is consistent with a malignant peripheral nerve sheath tumor, with foci of osteosarcoma representing a heterologous element. Such foci are not uncommon in these tumors. The tumor comes within 1 to 2 cells of an inked margin

History:

The patient is a [REDACTED] year old man, of unstated race, with a soft tissue buttock mass. Operative procedure: Wide

[page 2 of 3]
Patient Name: [REDACTED]

DOB: [REDACTED]

Patient ID: [REDACTED]

SURGICAL PATHOLOGY REPORT

excision.

Specimen(s) Received:

A: RIGHT HIP MASS

B: RIGHT HIP LARGE MASS

Gross Description:

The specimen is received in two formalin-filled containers labeled [REDACTED]. The first container is labeled "right hip mass" and "FS." It holds a tissue cassette labeled FS, that holds three portions of irregularly shaped white frozen section tissue remnants measuring 0.6 x 0.3 x 0.3 cm in aggregate. Labeled A. Jar 0.

The second container is labeled "right hip large mass, suture proximal." The container also indicates that a portion of the tissue was taken for tumor bank. The container holds an ellipse of non-pigmented skin measuring 6.1 x 1.4 cm in area. Attached to the ellipse of skin is a larger piece of soft tissue measuring 22 x 17 x 15 cm. There is a suture that denotes the proximal resection region. There is a small nodular area that has been previously inked black with a defect measuring 3.5 x 1.5 x 0.5 cm, consistent with area used for tissue bank. The position will be arbitrarily designated as the 12 o'clock position. The specimen is inked as follows: from 12 o'clock to 3 o'clock to 6 o'clock - yellow, from 6 o'clock to 9 o'clock to 12 o'clock - blue, and posterior/deep margin. Inked black. Sectioned to show a 19.0 x 11.5 x 8.5 cm heterogeneous, solid and cystic tan mass. The cystic areas contain hemorrhagic fluid. The solid areas are lobulated with scattered areas of yellow. The entire mass is well circumscribed and unencapsulated. The mass appears to abut the posterior fascial margin. Labeled B1 to B10 - proximal portions of the mass; B11 to B19 - distal sections of the mass; B20 - skin. Jar 4.

Addenda/Procedures

Addendum Ordered:

Addendum Complete:

Addendum Signed Out:

Status: Signed Out

By:

Addendum Diagnosis

Fluorescence In-situ Hybridization (FISH) Results:

Specimen: [REDACTED]

NEGATIVE - FISH result for MLL gene rearrangement

NEGATIVE - FISH result for ALK gene rearrangement

nuc ish(5'MLLx2-5.3'MLLx3-6)(5'MLL con 3'MLLx2-5)(16/200)/(MLLx6-10)(16/200)
(MLLx4-5)(78/200)/(MLLx3)(53/200)/(MLLx2)(33/200)

nuc ish(ALKx7-12)(22/200)/(ALKx4-6)(91/200)/(ALKx3)(46/200)/(ALKx2)(36/200)

Addendum Comment

MLL-BA FISH

FISH was performed utilizing a commercial MLL (11q23) break apart probe set. In this particular case, a split of red and green signals was not detected in 200 interphase cells examined. Therefore, there is no evidence for a MLL-containing chromosomal rearrangement. Gain of MLL was noted with 3-10 copies seen in 73.5%. Additionally, there was a subpopulation of cells expressing 3-5 copies of the MLL gene with an extra 3' signal (red) in 8%, the significance of which, if any, is unclear.

[page 3 of 3]
Patient Name: [REDACTED]

DOB: [REDACTED]

Patient [REDACTED]

GENETIC PATHOLOGY REPORT

ALK-BA FISH

FISH for ALK-gene rearrangement at chromosomal locus 2p23 was performed utilizing [REDACTED] FISH probe kit. The [REDACTED] FISH Probe Kit is a qualitative test to detect rearrangements involving the ALK gene via fluorescence in situ hybridization (FISH) in formalin-fixed paraffin-embedded (FFPE) non-small cell lung cancer (NSCLC) tissue specimens to aid in identifying those patients eligible for treatment with (crizotinib). The [REDACTED] follows the manufacturer's guidelines in the processing and analysis of this FDA-approved IVD FISH probe.

Positive for gene rearrangement: $\geq 15\%$ of a minimum of 100 interphase cells with positive signal pattern
Negative for gene rearrangement: $< 15\%$ of a minimum of 100 interphase cells with positive signal pattern

Comment: This case was negative for ALK gene rearrangement according to the above criterion. A gain of ALK was noted; 3-12 copies of ALK were observed in 79% of the 200 nuclei examined, the significance of which, if any, is unclear.

Reference: FFPE FISH Probe Kit Package

FFPE in-situ hybridization analysis was performed in the

Surgical Pathology report is available on-line on

END OF REPORT

Page 3 of 3

Page: 3 of 3

Printed from

Source: NCI Genomic Data Commons file 5a0ed758-ca2c-4d1d-8c02-dd292e83a735 (TCGA-SI-A71O.69A5812B-1109-4A09-928E-158B2A55E81E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).